Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3X1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3X1-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age):

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

year old with pT2 urothelial cell carcinoma, status post 2 courses of BCG.

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries anterior vaginal wall, bladder, perivesical lymph nodes
- 2: SP: Right distal pelvic lymph nodes
- 3: SP: Left pelvic lymph node
- 4: SP: Left distal pelvic lymph nodes
- 5: SP: Right distal ureter
- 6: SP: Left distal ureter

DIAGNOSIS:

1. SP: Uterus, cervix, bilateral tubes and ovaries anterior vaginal wall, bladder, perivesical lymph nodes:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

In situ component not identified

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Ureters uninvolved

Vascular Invasion:

No definite vascular invasion present

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

See also parts 5 and 6

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Exhibiting foreign body reaction

ICD-O-3

Carcinoma, urothelial, NOS

8120/3

Site: bladder, dome

C67.1

5-23-12, RP

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Female Genital Organs:

The endometrium shows endometrial polyp
The myometrium shows mural leiomyomas
The left fallopian tube shows simple serous cysts
The right ovary shows hilus cell and stromal hyperplasia
The left ovary shows stromal hyperplasia
Remaining genital organs are unremarkable

Perivesical Lymph Nodes:

LN Not involved 0/1

The Pathologic Stage is (AJCC

pT3 (Invasion of perivesicle soft tissue)

2. SP: Right distal pelvic lymph nodes:

Lymph Nodes:

Not involved

Number of nodes examined:2

3. SP: Left pelvic lymph node:

Lymph Nodes:

Not involved

Number of nodes examined:8

4. SP: Left distal pelvic lymph nodes:

Lymph Nodes:

Not involved

Number of nodes examined:8

5. Right distal ureter; excision:

- Ureter with focal mild atypia.

6. Left distal ureter; excision:

- Benign ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "uterus, cervix, bilateral tubes and ovaries, anterior vaginal wall, bladder and perivesical lymph nodes". It consists of a cystectomy-hysterectomy and bilateral salpingo-oophorectomy specimen measuring 11 cm from superior to inferior, 12cm laterally and 5cm from anterior to posterior. The bladder measures 13 x 11cm, the uterus measures 5 x 4.6 x 2.8 cm, the right ovary measures 2.2 x 1.0 x 0.9 cm, the right fallopian tube measures 5.4 x 0.7 cm, the left ovary measures 2.7 x 1.3 x 0.9 cm, and the left fallopian tube measures 4 x 0.7 cm. The portion of vaginal cuff measures 5.5 x 2.0 cm. The distal urethral margin and the vaginal cuff margin are shaved and submitted. The ureteric stumps are buried in the specimen, measure approximately 2 cm and show probe-patent lumen. The specimen is inked black for posterior, blue for anterior and the bladder is opened anteriorly to reveal a friable fungating mass measuring 3.3 x 2.4 cm located in the dome focally extending to trigone. The distance from the left and the right ureteric orifices are 5.2 cm and 5.3 cm respectively. On sectioning, the tumor extends to a depth

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

of 2.0 cm, and appears to extend into the perivesical fat grossly reaching to the subserosa. The remaining bladder mucosa shows flat mucosa without additional lesion. Discrete perivesical lymph nodes are not identified. The uterus is bivalved to reveal multiple fibroids ranging from 0.5 to 1.5 cm and endometrial polyp measuring 2 x 1.2 x 0.2 cm. The ovaries and fallopian tubes are unremarkable. Tissue is submitted for . Gross photograph is taken. Representative sections are submitted.

Summary of sections:

UTHM - urethral margin
RUM - right ureter margin
LUM -left ureter margin
L -lesion
RUO -right ureteric orifice
LUO -left ureteric orifice
LP-left posterior wall
LA -left anterior wall
RP-right posterior wall
RA -right anterior wall
TRI -trigone
EMM -endomyometrium
CX-cervix
V – vagina, full thickness to include bladder mucosa
DVM -distal vaginal margin
RTO -right tube and ovary
LTO-left tube and ovary
LN – possible lymph node

2). The specimen is received fresh , labeled "Right distal pelvic lymph nodes" and consists of 2 pink tan firm lymph nodes measuring 0.7 x 0.6 cm and 2.0 x 1.0 cm in greatest dimension. The larger lymph node is inked black and bisected. All identified lymph nodes are submitted.

Summary of sections:

LN – lymph nodes

3). The specimen is received fresh labeled "Left pelvic lymph nodes". It consists of multiple lymph nodes ranging from 0.2 x 0.2 cm up to 3 x 1.8 cm. The lymph nodes are serially sectioned at 3 mm intervals and submitted.

Summary of sections:

LN-lymph nodes
BLN-bisected lymph node
LN1-lymph node number one
LN2-lymph node number two
LN3-lymph node number three

4).The specimen is received fresh, labeled "Left distal pelvic lymph node" and consists of multiple pink tan firm lymph nodes ranging from 0.2 x 0.2 cm up to 3.5 x 1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN – lymph nodes
BLN– bisected lymph node

5). The specimen is received in formalin labeled "Right distal ureter unclipped is a margin." It consists of a segment of ureter measuring 5 cm in length and 0.4 cm in diameter. The attached adipose tissue measures up to 1.5 cm in thickness. There is a clip on one end of the specimen. The specimen is serially sectioned from the clipped to the non-clipped end and submitted entirely.

Summary of sections:

MC-margin with clip
SS-serial sections from clipped to non-clipped end

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

margin without clip

6). The specimen is received in formalin labeled "Left distal ureter unclipped is a margin." It consists of a segment of ureter measuring 3.5 cm in length and 0.4 cm in diameter. The attached adipose tissue measures up to 1.5 cm in thickness. There is a clip on one end of the specimen. The specimen is serially sectioned from the clipped to the non-clipped end and submitted entirely.

Summary of sections:

MC-margin with clip

SS-serial sections from clipped to non-clipped end

MWC-margin without clip

Summary of Sections:

Part 1: SP: Uterus, cervix, bilateral tubes and ovaries anterior vaginal wall, bladder, perivesical lymph nodes

Block	Sect. Site	PCs
1	cx	2
1	dnm	1
2	emm	2
6	L	6
1	la	2
1	LN	1
1	lof	2
1	lp	2
1	lum	1
1	luo	1
1	ra	2
1	rof	2
1	rp	1
1	rum	1
1	ruo	1
1	tri	1
1	uthm	1
1	v	1

Part 2: SP: Right distal pelvic lymph nodes

Block	Sect. Site	PCs
1	ln	1

Part 3: SP: Left pelvic lymph node

Block	Sect. Site	PCs
1	bln	1
1	ln	1
2	ln1	2
2	ln2	2
2	ln3	2

Part 4: SP: Left distal pelvic lymph nodes

Block	Sect. Site	PCs
1	BLN	1
1	LN	1

Part 5: SP: Right distal ureter

Block	Sect. Site	PCs
1	mc	1

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

1	mwc	1
1	ss	1

Part 6: SP: Left distal ureter

Block	Sect. Site	PCs
1	MC	1
1	MWC	1
1	SS	1

Source: NCI Genomic Data Commons file c6fd46ed-d506-494e-ac21-ae7c1087fe2b (TCGA-DK-A3X1.45B099D5-2E5F-4B70-9B17-D37BC5CA0D40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).